Somatic mutation profile of tumor specimen TCGA-AG-4001-01A (aliquot TCGA-AG-4001-01A-02W-1073-09) from TCGA case TCGA-AG-4001, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.7 years (27,302 days).
Specimen TCGA-AG-4001-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1979638a-3b90-40bc-bec3-5fd34ea73e21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-4001-10A (Blood Derived Normal), aliquot TCGA-AG-4001-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e20211df-19f0-48f6-ba91-33473c2dc65f

The open-access MAF lists 127 somatic variants for this specimen: 94 protein-altering or splice-affecting, 28 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 28, Nonsense Mutation 10, Frame Shift Del 5, RNA 4, Frame Shift Ins 2, Splice Site 2, Splice Region 1, Intron 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 78/223 reads (35%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.522G>A p.M174I | Missense Mutation (SNP) | VAF 75/196 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55602894; called by muse, mutect2, varscan2
- ADCY1 | c.3195C>G p.I1065M | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as COSV52043943; called by muse, mutect2
- AFF3 | c.1955C>T p.T652M | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.891); catalogued as rs764752937, COSV57877386; called by muse, mutect2, varscan2
- AFM | c.978A>C p.L326F | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56922624; called by muse, mutect2, varscan2
- AMOTL1 | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.319); catalogued as rs770787342, COSV58567771; called by muse, mutect2, varscan2
- ANXA1 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 83/230 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs752285742, COSV57412673; called by muse, mutect2, varscan2
- BCAS3 | c.1117G>C p.G373R | Missense Mutation (SNP) | VAF 168/586 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66783502; called by muse, mutect2, varscan2
- BCL9 | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs782764451, COSV52351201; called by muse, mutect2, varscan2
- C7orf31 | c.1667G>A p.R556H | Missense Mutation (SNP) | VAF 26/388 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.045); catalogued as rs779055753, COSV52216024; called by muse, mutect2
- CACNB3 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs748818201, COSV56401168; called by muse, mutect2, varscan2
- CC2D2A | c.4757T>C p.I1586T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs764003107, COSV100378093; called by muse, mutect2, varscan2
- CCT4 | c.1159A>G p.T387A | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs769218948, COSV66702234; called by muse, mutect2, varscan2
- CLEC4C | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs750777690, COSV63582321; called by muse, mutect2, varscan2
- CNTN3 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.317); catalogued as rs775718393, COSV55163242; called by muse, mutect2, varscan2
- CTDSPL2 | c.1117C>T p.R373W | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52946115; called by muse, mutect2, varscan2
- DAAM2 | c.3022C>T p.R1008W (on ENST00000274867 / NM_001201427.2; = p.R1007W on NM_015345.3) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs573237647, COSV51421591; called by muse, mutect2, varscan2
- DENND4A | c.4271C>G p.S1424* | Nonsense Mutation (SNP) | VAF 36/232 reads (16%) | catalogued as COSV71267197; called by muse, mutect2, varscan2
- DYSF | c.2755C>T p.R919C | Missense Mutation (SNP) | VAF 159/275 reads (58%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as rs755270902, COSV50595574; called by muse, mutect2, varscan2
- FAT4 | c.11483T>A p.V3828E | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58712590; called by muse, mutect2, varscan2
- FBN1 | c.2495G>C p.C832S | Missense Mutation (SNP) | VAF 76/469 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as CM096441, CM972801, COSV57332537; called by muse, mutect2, varscan2
- FSTL5 | c.1795G>A p.D599N | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as rs745600368, COSV60235627; called by muse, mutect2, varscan2
- H2BC9 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 53/74 reads (72%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); catalogued as rs1561760033, COSV55099491, COSV55099681; called by muse, mutect2, varscan2
- HSD17B10 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV51449041; called by muse, varscan2
- IFT80 | c.1825C>T p.R609C | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs186192085, COSV58453290; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGDCC3 | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.523); catalogued as rs368951025; called by muse, mutect2, varscan2
- IGLV2-8 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 85/377 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.488); catalogued as rs373694838; called by muse, mutect2, varscan2
- IQCB1 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 163/429 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767653545, COSV60439868; called by muse, varscan2
- KIF9 | c.1714G>A p.D572N (on ENST00000265529 / NM_001377474.1; = p.D507N on NM_022342.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs745616983, COSV55519233; called by muse, mutect2, varscan2
- KRIT1 | c.1460G>A p.W487* | Nonsense Mutation (SNP) | VAF 19/106 reads (18%) | catalogued as CM135506, COSV60671020; called by muse, mutect2, varscan2
- LRP1B | c.1410C>A p.V470= | Splice Region (SNP) | VAF 58/248 reads (23%) | catalogued as COSV101255040, COSV67281780; called by muse, mutect2, varscan2
- MAOB | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as rs1022361259, COSV65207128; called by muse, mutect2, varscan2
- MAP3K4 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 161/228 reads (71%) | catalogued as rs370191115, COSV62337015; called by muse, mutect2, varscan2
- MED12 | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 224/395 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as rs760696164, COSV61340682; called by muse, mutect2, varscan2
- MEMO1 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771196397, COSV54457484; called by muse, mutect2, varscan2
- MLF1 | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 45/262 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63035469; called by muse, mutect2, varscan2
- MSH6 | c.2935C>G p.L979V | Missense Mutation (SNP) | VAF 34/328 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.718); catalogued as rs1356451622, COSV52289773; ClinVar: uncertain significance; called by muse, mutect2
- MYH15 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/83 reads (12%) | PolyPhen benign (0); catalogued as rs763213333, COSV56321482; called by muse, mutect2, varscan2
- MYOM1 | c.4449C>A p.Y1483* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as COSV55302504; called by muse, mutect2, varscan2
- NCOR1 | c.2317A>T p.K773* | Nonsense Mutation (SNP) | VAF 30/70 reads (43%) | catalogued as COSV51999770; called by muse, mutect2, varscan2
- NDUFB9 | c.506A>G p.Y169C | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV52676516; called by muse, mutect2
- NELL2 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61586991; called by muse, mutect2, varscan2
- NFIB | c.1081C>G p.P361A | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.989); catalogued as COSV66628185; called by muse, mutect2, varscan2
- NR3C2 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.443); catalogued as rs375487193; called by muse, mutect2, varscan2
- OCA2 | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs372899234, COSV100667606; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR10G4 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 57/323 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs191928020, COSV57979339; called by muse, mutect2, varscan2
- OR10K2 | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 103/531 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV59220831, COSV59221326; called by muse, mutect2, varscan2
- OR2G6 | c.214T>C p.C72R | Missense Mutation (SNP) | VAF 59/274 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58575755, COSV58576087; called by muse, mutect2, varscan2
- OR5D18 | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 106/410 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as COSV61738934; called by muse, varscan2
- OTOGL | c.819G>T p.E273D (on ENST00000547103; = p.E264D on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV72007684; called by muse, mutect2, varscan2
- PCDHA13 | c.2177C>T p.P726L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV56507386, COSV99169700; called by muse, mutect2, varscan2
- PCDHB6 | c.2105C>T p.S702L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs782123595, COSV50693258; called by muse, mutect2, varscan2
- PGGHG | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1444677667, COSV66888716; called by muse, mutect2, varscan2
- PIK3C2B | c.2974C>T p.R992C | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1284556272, COSV65814672; called by muse, mutect2, varscan2
- PKHD1 | c.6866A>G p.D2289G | Missense Mutation (SNP) | VAF 328/502 reads (65%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV61897586; called by muse, mutect2, varscan2
- PPP4R4 | c.1266+2T>A p.X422_splice | Splice Site (SNP) | VAF 45/195 reads (23%) | catalogued as COSV100429101; called by muse, mutect2, varscan2
- PSG2 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 127/643 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs529547477, COSV61544553; called by muse, mutect2, varscan2
- SACS | c.6002G>T p.R2001I | Missense Mutation (SNP) | VAF 59/113 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV66547766; called by muse, mutect2, varscan2
- SETX | c.3650C>T p.T1217M | Missense Mutation (SNP) | VAF 104/387 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs140892948; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH3GL3 | c.313G>T p.G105W | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61062375; called by muse, mutect2, varscan2
- SLC16A2 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52084357; called by muse, mutect2, varscan2
- SLC35B3 | c.53C>A p.T18N | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV59470128; called by muse, mutect2, varscan2
- SLC44A5 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 112/265 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs373084017; called by muse, mutect2, varscan2
- SNX33 | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs1023883471, COSV57912857; called by muse, mutect2, varscan2
- SPATA4 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142260014; called by muse, mutect2, varscan2
- SPEF2 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 26/263 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772509398, COSV56796785; called by muse, mutect2, varscan2
- SPG11 | c.4562C>A p.S1521* | Nonsense Mutation (SNP) | VAF 25/195 reads (13%) | catalogued as COSV99969802; called by muse, mutect2, varscan2
- STAG2 | c.650A>G p.H217R | Missense Mutation (SNP) | VAF 161/577 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV54359830, COSV54374621; called by muse, mutect2, varscan2
- SUCLA2 | c.1243G>T p.A415S (on ENST00000643023; = p.A394S on NM_003850.3) | Missense Mutation (SNP) | VAF 281/620 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV66223229; called by muse, mutect2, varscan2
- SYBU | c.929G>A p.R310Q (on ENST00000276646 / NM_001099754.2; = p.R309Q on NM_017786.6) | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as rs1321101591, COSV52614331, COSV52621908, COSV52623741; called by muse, mutect2
- SYN1 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs760401568, COSV54482968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF1 | c.470G>A p.G157D | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV52127778; called by muse, mutect2, varscan2
- TP53 | c.365_366del p.V122Dfs*26 | Frame Shift Del (DEL) | VAF 71/164 reads (43%) | catalogued as rs587780067; called by pindel, varscan2
- TRAPPC12 | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 51/138 reads (37%) | catalogued as COSV60852525; called by muse, mutect2, varscan2
- TRPM3 | c.3856C>T p.R1286C (on ENST00000357533 / NM_001366142.2; = p.R1141C on NM_020952.6) | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs148061413, COSV62597388; called by muse, mutect2, varscan2
- TRPS1 | c.3756C>A p.C1252* (on ENST00000220888 / NM_001330599.2; = p.C1265* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 37/250 reads (15%) | catalogued as COSV55265598; called by muse, mutect2, varscan2
- TSHZ2 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 52/580 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs780826702, COSV61588147; called by muse, mutect2
- TTN | c.100141G>A p.E33381K (on ENST00000591111; = p.E25957K on NM_003319.4) | Missense Mutation (SNP) | VAF 45/174 reads (26%) | PolyPhen probably damaging (0.994); catalogued as rs727504977, COSV60089185; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR13 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54333870; called by muse, mutect2
- ZC4H2 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.817); catalogued as rs771739567, COSV100565127, COSV62006654; called by muse, mutect2, varscan2
- ZCWPW2 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 51/403 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV67501678; called by muse, mutect2, varscan2
- ZFHX4 | c.2905C>G p.Q969E | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV51500410; called by muse, mutect2, varscan2
- ZNF157 | c.30A>T p.R10S | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV65659931; called by muse, mutect2
- ZNF560 | c.463A>C p.K155Q | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV56872374; called by muse, mutect2, varscan2
- ZNF586 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs993565997, COSV66972798; called by muse, mutect2, varscan2
- APC | c.4495_4510del p.G1499Pfs*3 | Frame Shift Del (DEL) | VAF 60/302 reads (20%) | called by mutect2, pindel, varscan2
- ARID2 | c.1351del p.S451Lfs*12 | Frame Shift Del (DEL) | VAF 216/586 reads (37%) | called by mutect2, pindel, varscan2
- CDH6 | c.1919dup p.E643Rfs*13 | Frame Shift Ins (INS) | VAF 79/311 reads (25%) | called by mutect2, pindel, varscan2
- IGLV2-14 | c.349A>T p.T117S | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IGLV7-46 | c.283A>C p.T95P | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- MUC16 | c.14209_14212del p.P4737Ffs*47 | Frame Shift Del (DEL) | VAF 72/607 reads (12%) | called by pindel, varscan2
- PDIA3 | c.1028+2dup p.X343_splice | Splice Site (INS) | VAF 19/83 reads (23%) | called by mutect2, pindel, varscan2
- RNF43 | c.2224dup p.E742Gfs*5 | Frame Shift Ins (INS) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- USP34 | c.329_330del p.E110Vfs*2 | Frame Shift Del (DEL) | VAF 53/503 reads (11%) | called by pindel, varscan2
- ADAM32 | c.1284C>T p.D428= | Silent (SNP) | VAF 20/134 reads (15%) | catalogued as rs189440658, COSV65947351, COSV65950565; called by muse, mutect2, varscan2
- C11orf87 | c.321C>T p.S107= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs768536867, COSV59357576; called by muse, mutect2
- CABIN1 | c.2295C>T p.N765= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs771270819, COSV54090532; called by muse, mutect2, varscan2
- CBLB | c.1401C>T p.V467= | Silent (SNP) | VAF 11/135 reads (8%) | catalogued as COSV99914565; called by muse, mutect2
- CFAP221 | c.2199C>T p.D733= | Silent (SNP) | VAF 42/247 reads (17%) | catalogued as COSV54664023; called by muse, mutect2, varscan2
- CLASP2 | c.565T>C p.L189= | Silent (SNP) | VAF 116/935 reads (12%) | catalogued as COSV56295798; called by muse, mutect2, varscan2
- CLEC14A | c.939C>T p.P313= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs765743832, COSV60564609; called by muse, mutect2, varscan2
- CLIC4 | c.639A>G p.E213= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV65527904; called by muse, mutect2, varscan2
- CNGB1 | c.1881C>T p.C627= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as rs369525244, COSV51900241; called by muse, mutect2, varscan2
- EEF1AKMT2 | c.609C>T p.F203= | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as COSV63042146; called by muse, mutect2, varscan2
- FHL1 | c.6G>A p.A2= | Silent (SNP) | VAF 105/241 reads (44%) | catalogued as COSV61779756; called by muse, mutect2, varscan2
- GLRB | c.1431A>T p.A477= | Silent (SNP) | VAF 67/322 reads (21%) | catalogued as COSV52423313; called by muse, mutect2, varscan2
- GRIN2A | c.963C>T p.Y321= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as rs368200727; ClinVar: likely benign; called by muse, mutect2, varscan2
- IBTK | c.3615G>A p.R1205= | Silent (SNP) | VAF 44/251 reads (18%) | catalogued as rs1302756074, COSV60396727; called by muse, mutect2, varscan2
- MMP2 | c.627C>T p.D209= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as rs778038179, COSV54599041; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH11 | c.105C>T p.L35= | Silent (SNP) | VAF 24/124 reads (19%) | catalogued as rs779367784, COSV55572699; called by muse, mutect2, varscan2
- OPN1LW | c.642C>T p.P214= | Silent (SNP) | VAF 108/236 reads (46%) | catalogued as rs138979991, COSV64049614; called by muse, mutect2, varscan2
- PCDH19 | c.936C>T p.Y312= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs1314186595, COSV55268514; called by muse, mutect2, varscan2
- PPP2R5A | c.231G>A p.Q77= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV54815146; called by muse, mutect2, varscan2
- PRRC2A | c.3574C>T p.L1192= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as COSV65689348; called by muse, mutect2, varscan2
- PSG4 | c.1161G>A p.K387= | Silent (SNP) | VAF 64/370 reads (17%) | catalogued as rs776868878, COSV54941957; called by muse, mutect2, varscan2
- RAPGEF3 | c.2193G>A p.R731= (on ENST00000389212; = p.R689= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV50246626; called by muse, mutect2, varscan2
- SLC1A6 | c.1449C>T p.V483= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as rs776435229, COSV55668777; called by muse, mutect2, varscan2
- THOC2 | c.2337G>A p.Q779= | Silent (SNP) | VAF 385/902 reads (43%) | catalogued as COSV55557082; called by muse, mutect2, varscan2
- TMPRSS11F | c.621C>G p.V207= | Silent (SNP) | VAF 29/159 reads (18%) | catalogued as COSV62469993; called by muse, mutect2, varscan2
- ZNF280C | c.9C>T p.D3= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as rs758815792, COSV100921246, COSV63970125; called by muse, mutect2, varscan2
- ZNF507 | c.2271A>G p.Q757= | Silent (SNP) | VAF 54/133 reads (41%) | catalogued as rs761591273, COSV61333716; called by muse, mutect2, varscan2
- ZNF804A | c.684C>A p.S228= | Silent (SNP) | VAF 68/334 reads (20%) | catalogued as COSV56474760; called by muse, mutect2, varscan2
- AC073310.1 | n.946C>T | RNA (SNP) | VAF 107/326 reads (33%) | called by muse, mutect2, varscan2
- AGAP7P | n.1349G>A | RNA (SNP) | VAF 36/119 reads (30%) | catalogued as rs553006355; called by muse, mutect2, varscan2
- CFLAR | c.523+309C>T | Intron (SNP) | VAF 5/42 reads (12%) | catalogued as rs533106260, COSV100009993; called by mutect2, varscan2
- SNORD114-25 | n.50G>A | RNA (SNP) | VAF 62/221 reads (28%) | catalogued as rs762253283; called by muse, mutect2, varscan2
- SPATA8 | n.747A>T | RNA (SNP) | VAF 8/60 reads (13%) | catalogued as COSV60705761; called by muse, mutect2, varscan2
